Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4894, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4894-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) LEFT KIDNEY, ADRENAL GLAND AND RENAL VEIN THROMBUS:
RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN NUCLEAR GRADE 3.
TUMOR MEASURES 11.0 CM IN MAXIMUM DIMENSION.
TUMOR THROMBUS IN RENAL VEIN.
TUMOR FOCALLY INVADES PERIRENAL ADIPOSE TISSUE.
Margins of resection, free of tumor.
Renal parenchyma with focal cortical hemorrhages, interstitial nephritis and fibrosis.
Renal cortical (simple) cysts.
Adrenal gland, no tumor present.
- (B) RETROPERITONEAL LYMPH NODES:
Three lymph nodes, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY, ADRENAL GLAND, AND RENAL VEIN THROMBUS - A radical nephrectomy specimen (27.0 x 13.0 x 8.0 cm in toto) including kidney (15 x 7 x 6 cm), with the attached ureter (1.1 x 0.5 cm) and the unremarkable adrenal gland (6.0 x 4.5 x 1.0 cm).

A thrombus (2.5 x 1.5 x 1.5 cm) is present within the renal vein and is focally attached to the vascular wall. An ill-defined multilobulated tumor (11.0 x 7.5 x 7.0 cm) replaces majority of the inferior half of the kidney, invading into the perinephric adipose tissue inferiorly and pushes into the renal sinus adipose tissue. The tumor has a heterogeneous appearance with large areas of hemorrhage and tan-brown solid areas.

A large cyst (3.5 x 3.0 x 2.5 cm) is filled with clear fluid in the mid pole of the kidney, and multiple other small cysts (0.2 cm in greatest dimension) filled with clear fluid are in the remaining upper pole kidney. Multiple areas of cortical hemorrhage (1.0 cm in greatest dimension) are present diffusely in the remaining upper pole kidney parenchyma. The adrenal gland is far from the tumor (8.0 cm away).

SECTION CODE: A1, ureter margin en face; A2, vascular margin en face; A3, A4, thrombus inside the renal vein, with the vascular wall; A5-A9, tumor; A10-A13, tumor with adjacent inferior perinephric adipose tissue; A14-A17, tumor with sinus adipose tissue invasion; A17-A19, tumor with pelvis; A20, A21, the larger cyst wall in the mid pole; A22, smaller cyst in upper pole; A23, A24, hemorrhagic areas in the cortex of upper pole; A25, unremarkable parenchyma; A26, adrenal gland.

(B) RETROPERITONEAL LYMPH NODES - Fragments of adipose tissue including three lymph nodes (3.0 x 2.5 x 1.5 cm in aggregate). The lymph nodes measure from 1.5 to 1.8 cm in greatest dimension. The lymph nodes are entirely submitted as follows: B1, B2, one lymph node serially sectioned; B3, one lymph node; B4, B5, one lymph node serially sectioned.

CLINICAL HISTORY

[page 2 of 2]
[REDACTED]

Left renal mass.

SNOMED CODES

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 37a2f90e-17dd-40f2-8aea-3c3190714f45 (TCGA-CJ-4894.DECB42E3-853E-4430-80C0-6DC04922D4C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).